Somatic mutation profile of tumor specimen TCGA-R6-A6Y2-01B (aliquot TCGA-R6-A6Y2-01B-11D-A33E-09) from TCGA case TCGA-R6-A6Y2, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 71.0 years (25,940 days).
Specimen TCGA-R6-A6Y2-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73c70235-6f2e-4b49-9778-77fa7c509e36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A6Y2-10A (Blood Derived Normal), aliquot TCGA-R6-A6Y2-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bbbb507-dc92-4dc8-a6d5-b2b47df6c787

The open-access MAF lists 116 somatic variants for this specimen: 81 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 33, Nonsense Mutation 10, Frame Shift Del 2, RNA 1, Intron 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs864321707, CM164378, COSV60436134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 21/35 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALDOB | c.610T>C p.Y204H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.044); catalogued as rs374240733; called by muse, mutect2, varscan2
- CALR3 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs746871999; called by muse, mutect2, varscan2
- CPNE8 | c.1366A>G p.I456V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as rs1477031019, COSV99044784; called by muse, mutect2, varscan2
- CSF3R | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1461275355; called by muse, mutect2
- CTNND1 | c.2389C>T p.R797* (on ENST00000399050 / NM_001085458.2; = p.R791* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 28/69 reads (41%) | catalogued as COSV62387156; called by muse, mutect2, varscan2
- DAB2IP | c.607C>T p.P203S (on ENST00000408936; = p.P175S on NM_032552.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52267798; called by muse, mutect2, varscan2
- DYSF | c.4123C>T p.R1375W | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs368601323; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EDN3 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.8); PolyPhen benign (0.033); catalogued as rs536097197, COSV61107798; called by muse, mutect2, varscan2
- EXOC6B | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs769146629; called by muse, mutect2, varscan2
- FCRL5 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.358); catalogued as rs761819067; called by muse, mutect2, varscan2
- HDAC9 | c.1999C>T p.R667* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV67766146; called by muse, mutect2, varscan2
- HMBOX1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs777042809, COSV55065757; called by muse, mutect2, varscan2
- IGLV3-1 | c.286A>C p.T96P | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs774168565; called by muse, mutect2, varscan2
- INHBA | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV54220417; called by muse, mutect2, varscan2
- KCNQ5 | c.658A>G p.K220E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1255181523; called by muse, mutect2, varscan2
- KIAA1549 | c.4625G>A p.R1542H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769427032, COSV54314850; called by muse, mutect2, varscan2
- KIDINS220 | c.3233C>T p.A1078V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as rs753644163, COSV56758611; called by muse, mutect2, varscan2
- KLK4 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as rs267605602, COSV60676011; called by muse, mutect2, varscan2
- LHX9 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs772729961; called by muse, mutect2, varscan2
- MAL | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.218); catalogued as rs745452422, COSV100015848; called by muse, mutect2, varscan2
- MYPN | c.3848G>A p.R1283H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs372512501; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK3 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs760462632; called by muse, mutect2, varscan2
- P4HA2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as rs200355999, COSV51331615; called by mutect2, varscan2
- PCDH9 | c.943C>A p.Q315K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1419137376; called by muse, mutect2, varscan2
- PDZD2 | c.2839G>A p.G947R | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs384728, COSV56859525; called by muse, mutect2, varscan2
- RYR2 | c.12334G>A p.D4112N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63682979; called by muse, mutect2, varscan2
- SAMD9L | c.3643C>A p.P1215T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV59080159; called by muse, mutect2, varscan2
- SCP2D1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs903776476; called by muse, mutect2, varscan2
- SEMA3G | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as rs1297949367, COSV51594588; called by muse, mutect2
- SLC22A7 | c.1108G>A p.G370R (on ENST00000372585 / NM_153320.2; = p.G368R on NM_006672.3) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV51482643; called by muse, mutect2, varscan2
- SLITRK1 | c.1474G>C p.A492P | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as COSV65677758; called by muse, mutect2, varscan2
- SPTA1 | c.5197T>A p.L1733M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV63749514, COSV63749741; called by muse, mutect2, varscan2
- TRIM48 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 112/322 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as rs745847123, COSV101338380, COSV70161681; called by muse, mutect2, varscan2
- WHAMM | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.402); catalogued as rs753042412; called by muse, mutect2, varscan2
- XIRP2 | c.3964C>T p.R1322* (on ENST00000628543; = p.R1497* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as rs202158141; called by muse, mutect2, varscan2
- ZNF687 | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs375351311; called by muse, mutect2, varscan2
- ZNF699 | c.1887C>G p.Y629* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV58026481; called by muse, mutect2, varscan2
- ZNF804B | c.122A>C p.K41T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60824147; called by muse, mutect2, varscan2
- ADCK1 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- ADGRE1 | c.1163C>A p.S388Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- AKAP13 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ANGPTL4 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- APC | c.1839del p.A614Hfs*16 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- ARMC4 | c.914T>G p.F305C | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BORA | c.1095A>C p.S365= (on ENST00000613797; = p.S290= on NM_024808.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- CDH4 | c.234A>C p.K78N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CSF2RB | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- DCST1 | c.1859A>T p.Q620L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.214); called by muse, mutect2
- DNAJC13 | c.3684_3694del p.N1229Tfs*18 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel
- DNASE2B | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DPP6 | c.1045A>G p.S349G (on ENST00000377770 / NM_001364500.2; = p.S287G on NM_001936.5) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FCGBP | c.4874A>G p.K1625R | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.1); called by muse, mutect2
- FLG | c.10582G>A p.G3528R | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAB4 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.587); called by muse, mutect2
- H4C3 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- IARS1 | c.722A>T p.E241V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- IVL | c.755A>T p.Q252L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- KCNU1 | c.1243G>C p.A415P | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM6A | c.1346G>A p.W449* | Nonsense Mutation (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- LSM14A | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MPDZ | c.4384A>G p.T1462A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO16 | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- NEXN | c.941T>C p.F314S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAAF1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PBX1 | c.1135A>G p.S379G | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PBX3 | c.1293T>A p.D431E | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- PCDH9 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POP4 | c.190C>T p.H64Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by mutect2, varscan2
- PREX1 | c.4243C>T p.Q1415* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- RABGAP1 | c.1886A>T p.D629V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- RSRC2 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- SC5D | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2
- SLITRK1 | c.695A>G p.K232R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- TECRL | c.208A>T p.R70W | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- TIAL1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLE3 | c.2209C>T p.Q737* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- VIPAS39 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- VPS37A | c.572C>G p.P191R | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- ZC3H18 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- ALPI | c.708C>T p.Y236= | Silent (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- ANK3 | c.7312T>C p.L2438= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs745427841; called by muse, mutect2, varscan2
- ASTN2 | c.1200G>A p.T400= (on ENST00000313400 / NM_001365069.1; = p.T349= on NM_014010.5) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs186306768, COSV57769880; called by muse, mutect2, varscan2
- CACNA1E | c.2430C>G p.P810= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV62426135; called by muse, mutect2, varscan2
- CCNT2 | c.66G>T p.P22= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, varscan2
- DDB1 | c.3292C>T p.L1098= | Silent (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- DMAP1 | c.849C>T p.R283= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- EEF1D | c.675G>A p.G225= | Silent (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- EEF2 | c.810C>T p.N270= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs201754413; called by muse, mutect2, varscan2
- ELMO1 | c.1575G>A p.Q525= | Silent (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- FOXD4L3 | c.72C>T p.D24= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1554670718; called by mutect2, varscan2
- FTMT | c.378G>A p.A126= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV58419830, COSV58420814; called by muse, mutect2, varscan2
- GABRB3 | c.1398T>G p.V466= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV100160228; called by muse, mutect2
- IGSF11 | c.147C>T p.S49= (on ENST00000393775 / NM_001015887.3; = p.S48= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs746094445, COSV61167475; called by muse, mutect2, varscan2
- IL1A | c.300C>T p.I100= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as rs779488667, COSV54520679; called by muse, mutect2, varscan2
- KIF3C | c.2079G>T p.R693= | Silent (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- MAP3K6 | c.2163C>T p.F721= | Silent (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- MIER2 | c.1101C>T p.S367= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs769385391; called by mutect2, varscan2
- MYEF2 | c.1497C>A p.I499= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV51047340; called by muse, mutect2, varscan2
- N4BP3 | c.405G>A p.A135= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs377627701; called by muse, mutect2, varscan2
- OR1N1 | c.190C>T p.L64= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs539467595, COSV100509824, COSV59196420; called by muse, mutect2, varscan2
- PCDHA4 | c.660C>T p.P220= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs782247861, COSV63544159; called by muse, mutect2, varscan2
- PEX5L | c.720G>A p.P240= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs772646436; called by muse, mutect2, varscan2
- PIP5K1C | c.639G>A p.P213= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs768624331; called by muse, mutect2, varscan2
- RFC1 | c.1755C>T p.L585= | Silent (SNP) | VAF 29/43 reads (67%) | called by muse, mutect2, varscan2
- SLC30A2 | c.786G>A p.L262= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- SMAP1 | c.73C>T p.L25= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- TM9SF2 | c.129C>G p.P43= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs755254521, COSV100816411, COSV63480844, COSV63480861; called by mutect2, varscan2
- TRHDE | c.783C>T p.F261= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99669445; called by muse, mutect2, varscan2
- TTLL10 | c.1125G>A p.K375= (on ENST00000379289 / NM_001130045.2; = p.K302= on NM_153254.3) | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs1054935920; called by muse, mutect2, varscan2
- UNCX | c.417G>A p.A139= | Silent (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- VENTX | c.510C>T p.Y170= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs1282779090; called by muse, mutect2, varscan2
- ZNF423 | c.978C>T p.H326= (on ENST00000563137 / NM_001379286.1; = p.H318= on NM_015069.4) | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs377569533; called by muse, mutect2, varscan2
- CASP2 | c.967+128C>T | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- MIR137 | n.99G>A | RNA (SNP) | VAF 43/102 reads (42%) | catalogued as rs1357269837; called by muse, mutect2, varscan2
